Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A73X, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A73X-01A (Primary Tumor).

Carcinoma, tubular NOS 8211/3
Site: ^{C4CF} Breast NOS C50.9
path: Breast, central portion C50.1
Q210115/13

Patient: XXX

Age:

Gender: F

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Cancer of the left breast**

Date of admission:

Material:

1) Material: left breast; method of collection: Total organ resection

Supplement result:

Examination performed on:

Complementary macroscopic description:

Tumour sized 2.3 x 1.7 x 1.3cm on the boundary of upper quadrants (located centrally over the nipple, placed 2.5cm from the lower boundary, 0 cm from the base and 0.8cm from the skin).

Assistant:

Pathologist:

Edited by

Histopathological diagnosis:

Examination performed on:

Invasive tubular carcinoma of the breast. (NHG1; pT2; pNO(sn). (8211/3 T 04030)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Left breast, sized 18 x 14 x 1.5cm, removed without with a skin flap of 13 x 4.5cm. Weight 220 g. Tumour on the boundary of the upper quadrants (centrally over the nipple).

Microscopic description:

Invasive tubular carcinoma - NHG1 (1+1+1:0 mitoses/10 HPF - visual area: 0.60mm). Glandular tissue, outside the tumour, showing lesions of the fibrocystic type and fibroadenoma of 0.5 cm in diameter.

Assistant:

Pathologist:

Edited by

Results of intraoperative examination:

Examination performed on:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 75% of neoplastic cell nuclei. HER2 protein stained with

HER-2/neu (4B5).HER-2/neu (4B5) Rabbit Monoclonal Antibody

Negative reaction in invasive cancerous cells (Score = 1+)

The expression of proliferating nuclear antigen Ki 67 in 10 % cellular nuclei.

Assistant:

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 5fb10f7b-471b-4518-9f5d-7a3edb188ed3 (TCGA-D8-A73X.9B227A4E-6237-4C95-B640-E64AFF0CC5F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).